Somatic mutation profile of tumor specimen MP2PRT-PASYID-TMP1-A (aliquot MP2PRT-PASYID-TMP1-A-1-0-D-A80J-36) from MP2PRT case MP2PRT-PASYID, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.2 years (2,276 days).
Specimen MP2PRT-PASYID-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f29742f0-6894-4bf8-8159-771113da2c98.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASYID-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASYID-NB1-A-1-0-D-A80J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c3555da-b15e-4d4c-bfc4-82298f2d52e8

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 4, Nonsense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GCDH | c.1156C>T p.R386* | Nonsense Mutation (SNP) | VAF 208/443 reads (47%) | catalogued as rs752127949, CM002991, CM960716; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 141/322 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- GJA1 | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 29/733 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0.023); catalogued as rs1389609669; called by muse, mutect2
- PARD3B | c.3050G>A p.R1017H (on ENST00000406610 / NM_001302769.2; = p.R948H on NM_057177.7) | Missense Mutation (SNP) | VAF 110/267 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs773012716, COSV62513483; called by muse, mutect2, varscan2
- PCDHGA12 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 197/464 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.901); catalogued as COSV52757339, COSV52761794; called by muse, mutect2, varscan2
- PRSS51 | c.244C>T p.R82* | Nonsense Mutation (SNP) | VAF 89/230 reads (39%) | catalogued as rs546666814; called by muse, mutect2, varscan2
- SYK | c.1042T>A p.Y348N | Missense Mutation (SNP) | VAF 14/419 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as COSV65329338, COSV65329449; called by muse, mutect2
- TCP11 | c.679C>T p.R227W (on ENST00000512012; = p.R165W on NM_018679.5) | Missense Mutation (SNP) | VAF 155/527 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs954988108, COSV55133879; called by muse, mutect2, varscan2
- TTC28 | c.4945G>A p.G1649S | Missense Mutation (SNP) | VAF 22/582 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1020164310; called by muse, mutect2
- ADRA2C | c.900G>A p.A300= | Silent (SNP) | VAF 88/135 reads (65%) | called by muse, mutect2, varscan2
- ANKRD33 | c.516G>A p.P172= (on ENST00000340970 / NM_001304459.2; = p.P297= on NM_182608.4) | Silent (SNP) | VAF 322/676 reads (48%) | catalogued as rs201364500, COSV100001243; called by muse, mutect2, varscan2
- CCDC88B | c.2694G>A p.A898= | Silent (SNP) | VAF 192/416 reads (46%) | catalogued as rs200338718; called by muse, mutect2, varscan2
- DSC1 | c.2331G>A p.Q777= | Silent (SNP) | VAF 172/570 reads (30%) | called by muse, mutect2, varscan2
- MAGI2 | c.3706+5997C>T | Intron (SNP) | VAF 172/397 reads (43%) | called by muse, mutect2, varscan2
